Somatic mutation profile of tumor specimen TCGA-12-1600-01A (aliquot TCGA-12-1600-01A-01W-0643-08) from TCGA case TCGA-12-1600, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 86.0 years (31,419 days).
Specimen TCGA-12-1600-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c20579df-b808-4a24-8f27-5738bb970b90.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-12-1600-10A (Blood Derived Normal), aliquot TCGA-12-1600-10A-01W-0643-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/16a12858-dcc6-4b9d-86c8-08118dc6171d

The open-access MAF lists 68 somatic variants for this specimen: 50 protein-altering or splice-affecting, 17 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 17, Splice Site 5, Nonsense Mutation 3, 3'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYH3 | c.2015G>A p.R672H | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913617, CM061864, COSV56863939; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RB1 | c.951_954del p.S318Nfs*13 | Frame Shift Del (DEL) | VAF 64/72 reads (89%) | catalogued as rs1566194323; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.376-1G>A p.X126_splice | Splice Site (SNP) | VAF 8/19 reads (42%) | hotspot (GDC flag); catalogued as rs868137297, CS1313555, COSV52688618, COSV52749979, COSV52994579, COSV52996344; ClinVar: likely pathogenic / pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.159G>A p.W53* | Nonsense Mutation (SNP) | VAF 82/210 reads (39%) | hotspot (GDC flag); catalogued as rs1064794618, COSV52751414, COSV53223969, COSV53499187; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACTN4 | c.1007G>A p.R336H | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99399656; called by muse, mutect2, varscan2
- ADGRF4 | c.1520G>A p.R507H | Missense Mutation (SNP) | VAF 152/360 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs142222318; called by muse, mutect2, varscan2
- BLNK | c.1175G>A p.R392Q | Missense Mutation (SNP) | VAF 31/42 reads (74%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs372532123; called by muse, mutect2, varscan2
- BRD2 | c.346A>G p.I116V | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.317); catalogued as COSV100875523; called by muse, mutect2, varscan2
- CACNA2D1 | c.2572T>C p.F858L (on ENST00000356253 / NM_001366867.1; = p.F846L on NM_000722.4) | Missense Mutation (SNP) | VAF 91/376 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.281); catalogued as COSV100665189; called by muse, mutect2, varscan2
- CCR2 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 253/629 reads (40%) | catalogued as rs1322904635, COSV99431858; called by muse, mutect2, varscan2
- EGFR | c.2320G>A p.V774M | Missense Mutation (SNP) | VAF 964/2026 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs567477136, COSV51777313, COSV51843665; called by muse, varscan2
- ENPEP | c.1675C>T p.R559C | Missense Mutation (SNP) | VAF 97/230 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs544907084, COSV54453278; called by muse, mutect2, varscan2
- FAM189A2 | c.1262C>T p.A421V | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs569881416, COSV99975444; called by muse, varscan2
- FGL1 | c.539A>C p.E180A | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.524); catalogued as COSV101112404, COSV67711729, COSV67712055; called by muse, mutect2, varscan2
- GRXCR1 | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 155/387 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as rs764688285, COSV67670498; called by muse, mutect2, varscan2
- HTRA2 | c.1289C>G p.A430G | Missense Mutation (SNP) | VAF 72/239 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99239362; called by muse, mutect2, varscan2
- IQSEC2 | c.745G>A p.G249S (on ENST00000642864 / NM_001111125.3; = p.G44S on NM_015075.2) | Missense Mutation (SNP) | VAF 25/27 reads (93%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.832); catalogued as COSV100944677; called by muse, mutect2, varscan2
- IRGQ | c.531-1G>T p.X177_splice | Splice Site (SNP) | VAF 7/23 reads (30%) | catalogued as COSV100338026; called by muse, mutect2, varscan2
- KCNA5 | c.1762G>A p.V588I | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as rs779699586, COSV52906823; called by muse, mutect2, varscan2
- LRP2 | c.12229T>A p.Y4077N | Missense Mutation (SNP) | VAF 56/112 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as rs748742356, COSV99785788; called by muse, mutect2, varscan2
- MAMLD1 | c.1340T>C p.L447P | Missense Mutation (SNP) | VAF 61/95 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99475402; called by muse, mutect2, varscan2
- MS4A6A | c.619C>T p.R207W | Missense Mutation (SNP) | VAF 68/171 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs371493203, COSV60620392; called by muse, mutect2, varscan2
- NADSYN1 | c.646G>A p.V216M | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.324); catalogued as rs142449261; called by muse, mutect2, varscan2
- NECTIN4 | c.541G>A p.V181M | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.947); catalogued as rs749387977, COSV100919778; called by muse, mutect2, varscan2
- OR4A15 | c.107C>T p.T36M | Missense Mutation (SNP) | VAF 83/216 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.907); catalogued as rs199660751, COSV59033672; called by muse, mutect2, varscan2
- PDYN | c.637C>T p.R213C | Missense Mutation (SNP) | VAF 37/138 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs150455107; called by muse, mutect2, varscan2
- PLAA | c.566G>A p.G189E | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV101263470, COSV68304751; called by muse, mutect2, varscan2
- PPP1CB | c.296C>G p.S99C | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV56092007, COSV99941637; called by muse, mutect2, varscan2
- PPP1R3D | c.773G>A p.R258H | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.959); catalogued as rs980214045, COSV100674333; called by muse, mutect2, varscan2
- RNF183 | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 15/22 reads (68%) | SIFT tolerated (0.06); PolyPhen benign (0.077); catalogued as rs567410524, COSV99937941; called by muse, varscan2
- RORC | c.244C>T p.R82* | Nonsense Mutation (SNP) | VAF 15/29 reads (52%) | catalogued as COSV100561716; called by muse, mutect2, varscan2
- RPL14 | c.58C>T p.H20Y | Missense Mutation (SNP) | VAF 76/182 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0.006); catalogued as COSV100166093; called by muse, mutect2, varscan2
- SDK1 | c.6445G>A p.D2149N | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.546); catalogued as COSV67377042; called by muse, mutect2, varscan2
- SFRP1 | c.214G>T p.G72C | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99616769; called by muse, mutect2, varscan2
- SIM1 | c.1396G>A p.A466T | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.012); catalogued as COSV99491738; called by muse, mutect2, varscan2
- SLC6A16 | c.2042G>C p.C681S | Missense Mutation (SNP) | VAF 40/160 reads (25%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.63); catalogued as COSV100242509; called by muse, mutect2, varscan2
- SLC6A3 | c.1843C>T p.R615C | Missense Mutation (SNP) | VAF 43/128 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs763131939, CM1213422, COSV99547700; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SYT13 | c.689C>T p.A230V | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs764489678, COSV99194622; called by muse, mutect2, varscan2
- TAT | c.835G>A p.A279T | Missense Mutation (SNP) | VAF 91/199 reads (46%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.818); catalogued as COSV100587428; called by muse, mutect2, varscan2
- TCHHL1 | c.2699G>A p.S900N | Missense Mutation (SNP) | VAF 233/600 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.019); catalogued as COSV100916486; called by muse, mutect2, varscan2
- TGFA | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs782074408, COSV54913414, COSV54913742; called by muse, mutect2
- TMEM132D | c.968+1G>T p.X323_splice | Splice Site (SNP) | VAF 28/73 reads (38%) | catalogued as COSV101395845; called by muse, mutect2, varscan2
- TNFRSF8 | c.596G>A p.R199H | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs749228869, COSV55794828; called by muse, mutect2, varscan2
- UBXN11 | c.974-1G>C p.X325_splice (on ENST00000374221 / NM_183008.2; = p.X292_splice on NM_145345.2) | Splice Site (SNP) | VAF 18/50 reads (36%) | catalogued as COSV99581968; called by muse, mutect2, varscan2
- ZNF184 | c.2230C>T p.H744Y | Missense Mutation (SNP) | VAF 128/319 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99279314; called by muse, mutect2, varscan2
- ZNF384 | c.826C>T p.R276C | Missense Mutation (SNP) | VAF 49/127 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs777543241, COSV60533279; called by muse, mutect2, varscan2
- ZNF585A | c.338A>G p.Y113C (on ENST00000292841 / NM_001288800.2; = p.Y58C on NM_152655.3) | Missense Mutation (SNP) | VAF 265/873 reads (30%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.784); catalogued as rs371733011; called by muse, mutect2, varscan2
- ZNF831 | c.4868G>A p.R1623Q | Missense Mutation (SNP) | VAF 57/178 reads (32%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs552093905, COSV100925686, COSV64039327; called by muse, mutect2, varscan2
- FAM120B | c.2733_*11+3del p.X911_splice | Splice Site (DEL) | VAF 51/191 reads (27%) | called by mutect2, pindel, varscan2
- UBE2NL | c.133G>T p.D45Y | Missense Mutation (SNP) | VAF 64/75 reads (85%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- ALK | c.1998C>T p.P666= | Silent (SNP) | VAF 21/66 reads (32%) | catalogued as rs549825750, COSV101200768, COSV66555521, COSV66572515; ClinVar: likely benign; called by muse, mutect2, varscan2
- ATP12A | c.1767C>T p.D589= | Silent (SNP) | VAF 157/190 reads (83%) | catalogued as rs139332250, COSV54516093; called by muse, mutect2, varscan2
- AXDND1 | c.1617C>T p.Y539= | Silent (SNP) | VAF 97/242 reads (40%) | catalogued as rs142812354; called by muse, mutect2, varscan2
- C5 | c.2100C>T p.Y700= | Silent (SNP) | VAF 35/105 reads (33%) | catalogued as rs779822675, COSV99796879; called by muse, mutect2, varscan2
- CD109 | c.1812T>C p.D604= | Silent (SNP) | VAF 223/486 reads (46%) | catalogued as rs1220368264, COSV99752248; called by muse, mutect2, varscan2
- CETP | c.1293C>T p.T431= | Silent (SNP) | VAF 64/173 reads (37%) | catalogued as rs774124487, COSV52364341; called by muse, mutect2, varscan2
- COL14A1 | c.3462C>T p.S1154= | Silent (SNP) | VAF 65/139 reads (47%) | catalogued as COSV99917526; called by muse, mutect2, varscan2
- CYP4F8 | c.1215C>T p.D405= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as rs751652779, COSV57854401; called by muse, mutect2, varscan2
- FLNC | c.4254C>T p.D1418= | Silent (SNP) | VAF 46/160 reads (29%) | catalogued as rs773306584, COSV100367467; called by muse, mutect2, varscan2
- HCN1 | c.2103C>T p.T701= | Silent (SNP) | VAF 22/40 reads (55%) | catalogued as rs762033519, COSV57518789, COSV57525369; called by muse, mutect2, varscan2
- LVRN | c.531C>T p.D177= | Silent (SNP) | VAF 27/49 reads (55%) | catalogued as COSV63499250; called by muse, mutect2, varscan2
- MAPK15 | c.1233C>T p.P411= | Silent (SNP) | VAF 9/16 reads (56%) | catalogued as COSV100567631, COSV100568024; called by muse, mutect2, varscan2
- MOXD1 | c.765C>T p.H255= | Silent (SNP) | VAF 59/162 reads (36%) | catalogued as rs145443994, COSV60947129; called by muse, mutect2, varscan2
- NMBR | c.321C>T p.D107= | Silent (SNP) | VAF 47/124 reads (38%) | catalogued as COSV99237061; called by muse, mutect2, varscan2
- PCDH11Y | c.3807C>T p.V1269= | Silent (SNP) | VAF 126/135 reads (93%) | catalogued as COSV99290198, COSV99293003; called by muse, mutect2, varscan2
- PGLYRP4 | c.705T>C p.Y235= | Silent (SNP) | VAF 82/210 reads (39%) | catalogued as COSV100668257; called by muse, mutect2, varscan2
- UBXN10 | c.435C>A p.I145= | Silent (SNP) | VAF 63/135 reads (47%) | catalogued as COSV100907714; called by muse, mutect2, varscan2
- CALCA | chr11:14967804 C>T | 3'Flank (SNP) | VAF 98/256 reads (38%) | catalogued as rs782028430, COSV100523849; called by muse, mutect2, varscan2
